Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A815, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A815-01A (Primary Tumor).

Right adrenal

Date receiving:

Clinical history Hypertension diabetes since in the absence of overweight . Few vasomotor crisis. Discovery of a right highly vascularized adrenal mass measuring 43 mm. Chromogranin A: 332 µg/l. The I-MIBG scintigraphy is positive on pheochromocytoma.

Macroscopy

Right adrenalectomy weighing 40 g after fat dissection, measuring 7 x 5 x 3 cm with an buff-beige intra-adrenal nodule measuring 5.5 x 5 x 3 cm.

Microscopy

There is a tumor proliferation organized in cellular structures or in small clusters within an interstitial tissue sometimes fibrous, sometimes vascular with the presence of hemorrhagic lakes. The tumor cells are usually large. The cytoplasm is polygonal and moderately eosinophilic. The anisokaryosis is mild. The chromatin is pale. Presence of a small nucleolus more or less visible. In some areas, an increase in cellular density is observed with smaller cells layered in ranges with unsharp cytoplasmic limits and an increase of nucleocytoplasmic ratio. No necrosis or mitotic activity. The tumor is limited by a fibrous capsule of varying thickness separating from peri-adrenal adipose tissue and the adrenal. Presence in some areas of capsular infiltration and vascular invasion. No infiltration of peri-adrenal adipose tissue. The rest of the adrenal has a normal histological appearance without visible medullary hyperplasia.

CONCLUSION

Pheochromocytoma of the right adrenal gland measuring 5.5 cm long axis.
PASS score = 4 (high cellularity: 2; capsular invasion: 1, vascular invasion: 1)

Translated on from the original pathological report evaluated on

IGD-0-3
Pheochromocytoma NOS 8700/3
Site: R Adrenal gland NOS C74.9
QJ 10/17/13

Qual/Syn/chronous Primary		☒

Source: NCI Genomic Data Commons file 2877d811-0df5-4713-93f6-ddb24d04040d (TCGA-WB-A815.63554E83-28C2-4E07-8A65-0A102D736B4F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).